Surgical pathology report (de-identified scan), TCGA case TCGA-QK-A8Z7, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Emory University - Winship Cancer Inst., specimen TCGA-QK-A8Z7-01A (Primary Tumor).

[page 1 of 5]
Document Type: Anat Path Reports
Document Date:
Document Status:
Document Title:
Performed By:
Verified By:
Encounter info:

*Carcinoma, squamous cell,
basaloid 8083/3
Site: Floor mouth
8004.9
9/11/14*

*** Final Report ***

(Verified)

Patient Name: [REDACTED]
MRN: [REDACTED]
Location:
Client:
Submitting Phys:

DOB: [REDACTED]
Gender: M

Acc #:
Head and Neck
Collected:
Received:
Reported:

Final Surgical Pathology Report

Final Pathologic Diagnosis

- A. MANDIBLE AND SOFT TISSUE, COMPOSITE RESECTION:
- INVASIVE SQUAMOUS CELL CARCINOMA WITH BASALOID FEATURES (2.7 x 2.0 x 2.0 CM).
- SURGICAL RESECTION MARGINS ARE NEGATIVE FOR CARCINOMA.
- TUMOR COMES TO 0.6 CM FROM THE NEAREST DEEP SOFT TISSUE EDGE AT POSTEROLATERAL ASPECT (FOR FINAL MARGIN STATUS SEE PART "J").
- TUMOR INVADES MANDIBLE AND MUSCLE TISSUE.
- B. SALIVARY GLAND AND LYMPH NODES, LEFT NECK LEVEL 1, DISSECTION:
- SALIVARY GLAND WITH CHRONIC SIALADENITIS.
- ONE LYMPH NODE POSITIVE FOR METASTATIC CARCINOMA (1/1).
- C. LYMPH NODES, LEFT FACIAL, DISSECTION:
- FOUR LYMPH NODES NEGATIVE FOR METASTATIC CARCINOMA (0/4).
- D. LYMPH NODES, NECK LEVEL 1A, DISSECTION:
- FOUR LYMPH NODES NEGATIVE FOR METASTATIC CARCINOMA (0/4).
- E. LYMPH NODES, LEFT NECK LEVEL 5, DISSECTION:
- SEVEN LYMPH NODES NEGATIVE FOR METASTATIC CARCINOMA (0/7).
- F. LYMPH NODES, LEFT NECK LEVEL 4, DISSECTION:
- SEVEN LYMPH NODES NEGATIVE FOR METASTATIC CARCINOMA (0/7).
- G. LYMPH NODES, LEFT NECK LEVEL 2, DISSECTION:
- TEN LYMPH NODES NEGATIVE FOR METASTATIC CARCINOMA (0/10).
- H. LYMPH NODES, LEFT NECK LEVEL 3, DISSECTION:
- THREE OF TWELVE POSITIVE FOR METASTATIC CARCINOMA (3/12).

COMMENT: THE LARGEST DEPOSIT COULD REPRESENT EITHER AN OBLITERATED LYMPH NODE OR A

[page 2 of 5]
SOFT TISSUE DEPOSIT

- I. ANTERIOR GINGIVA, INK MARKS TRUE MARGIN:
- SQUAMOUS EPITHELIUM AND UNDERLYING MUSCLE NEGATIVE FOR CARCINOMA.
- J. LEFT MYOHYOID, EXCISION:
- MUSCLE TISSUE NEGATIVE FOR CARCINOMA.
- K. LYMPH NODES, RIGHT NECK LEVEL 1, DISSECTION:
- ONE OF THREE LYMPH NODES POSITIVE FOR CARCINOMA (1/3).
- L. ANTERIOR MANDIBLE, PARTIAL MANDIBULECTOMY:
- MANDIBLE MARGINS NEGATIVE FOR CARCINOMA.
- M. LYMPH NODES, RIGHT NECK LEVEL 5, DISSECTION:
- TWENTY FOUR LYMPH NODES NEGATIVE FOR METASTATIC CARCINOMA (0/24).
- N. LYMPH NODES, RIGHT NECK LEVEL 2, 3, 4, DISSECTION:
- TWENTY LYMPH NODES NEGATIVE FOR METASTATIC CARCINOMA (0/20).

Electronically Signed by

Assisted by:

Synoptic Worksheet

A. Composite resection:

Specimen:	Floor of mouth, NOS Mandible
Received:	Fresh
Procedure:	Mandibulectomy: anterior
Specimen Integrity:	Intact
Specimen Size:	Greatest dimension: 7.0 cm Additional dimension: 4.8 cm Additional dimension: 3.4 cm
Specimen Laterality:	Midline
Tumor Site:	Floor of mouth, NOS
Tumor Focality:	Single focus
Tumor Size:	Greatest dimension: 2.6 cm Additional dimension: 2.0 cm Additional dimension: 2.0 cm
Histologic Type:	Basaloid squamous cell carcinoma
Histologic Grade:	Not applicable
Margins:	Margins uninvolved by invasive carcinoma Distance from closest margin: 0.6 Unit of measurement: cm Margin(s): deep (right-posterior aspect) Margins uninvolved by carcinoma in situ (includes moderate and severe dysplasia)
Lymph-Vascular Invasion:	Not identified
Perineural Invasion:	Not identified
Lymph Nodes, Extranodal Extension:	Not identified
Pathologic Staging (pTNM):	
TNM Descriptors:	Not applicable

[page 3 of 5]
Primary Tumor (pT):	pT4a: Moderately advanced local disease. Lip: Tumor invades through cortical bone, inferior alveolar nerve, floor of mouth, or skin of face, ie, chin or nose. Oral cavity: Tumor invades adjacent structures only
Regional Lymph Nodes (pN):	pN2c: Metastasis in bilateral or contralateral lymph nodes, none more than 6 cm in greatest dimension Number of regional lymph nodes examined: 96 Number of regional lymph nodes involved: 5 Size (greatest dimension) of the largest positive lymph node: 3.0 cm
Distant Metastasis (pM):	Not applicable

Clinical History

Floor of mouth cancer. Floor of mouth excision, mandibulectomy, bilateral neck dissection, tracheotomy, radial forearm versus fibula free flap skin graft, possible PCC.

Specimen(s) Received

A: Composite resection
B: Left neck level 1
C: Left facial nodes
D: Level 1A
E: Left neck level 5
F: Left neck level 4
G: Left neck level 2
H: Left neck level 3
I: Anterior gingiva, ink marks true margin
J: Left myohyoid
K: Rt. level 1
L: Ant. mandible
M: Right neck level 5
N: Right neck level 2, 3, 4

Gross Description

Fourteen specimens are received, labeled with the patient's name and medical record number. Specimen A is received fresh for intraoperative consultation and specimens B-N are received in formalin.

Specimen A is labeled "composite resection." It consists of a partial mandibulectomy specimen with attached soft tissue measuring in toto, 7.0 x 4.8 x 3.4 cm. There are four disrupted teeth and a tooth root. The cut surface of the soft tissue reveals a white firm lesion measuring 2.7 x 2.0 x 2.0 cm. This lesion comes to within 0.3 cm from the deep edge on the left posterior aspect and comes to within 0.6 cm from the deep margin on the right posterior aspect. The tumor grossly involves the mandible. The soft tissue margin is inked black. Sections are submitted as follows:
Dictated by

Specimen B is labeled "left neck level 1." It consists of a salivary gland measuring 4.1 x 2.3 x 1.2 cm. It also contains a separate fibroadipose fragment measuring 2.0 x 1.8 x 1.0 cm. The cut surface of the salivary gland shows no masses or lesions. The outer surface of the salivary gland is inked black. The specimen is submitted as follows:
Dictated by

Specimen C is labeled "left facial node" and consists of multiple fragments of fibroadipose tissue with lymph nodes measuring in aggregate, 3.0 x 2.5 x 0.7 cm. The specimen is dissected for lymph nodes which are submitted entirely as follows: Dictated by

Specimen D is labeled "level 1A" and consists of a fragment of fibroadipose tissue measuring 4.0 x 2.3 x 0.8 cm. The specimen is dissected for lymph nodes which are entirely submitted as follows: Dictated by

Specimen E is labeled "left neck level 5." It consists of a fragment of fibroadipose tissue measuring 6.4 x 4.0 x 1.5 cm. The specimen is dissected for lymph nodes which are entirely submitted as follows: Dictated by

[page 4 of 5]
Specimen F is labeled "left neck level IV." It consists of a fragment of fibroadipose tissue measuring 4.5 x 3.0 x 1.6 cm. The specimen is dissected for lymph nodes which are entirely submitted as follows: Dictated by

Specimen G is labeled "left neck level 2" and consists of a fragment of fibroadipose tissue and muscle measuring 9.8 x 4.0 x 3.0 cm. The specimen is dissected for lymph nodes which are submitted as follows: Dictated by

Specimen H is labeled "left neck level III" and consists of a fragment of fibroadipose tissue and muscle measuring in toto, 5.9 x 4.7 x 4.5 cm. The cut surface reveals multiple positive lymph nodes ranging in size from 1.0 x 1.0 x 0.6 cm to 3.0 x 3.0 x 2.5 cm. Sections are submitted as follows: Dictated by

Specimen I is labeled "anterior gingiva; ink true margin" and consists of a fragment of mucosa and underlying soft tissue measuring 5.5 x 1.8 x 0.8 cm. The specimen is oriented with blue ink marking the true margin. Blue ink is reapplied to this surface. The specimen is serially sectioned and submitted entirely in cassettes "I1" through "I3." Dictated by

Specimen J is labeled "left mylohyoid" and consists of a fragment of unoriented muscle measuring 3.0 x 1.7 x 1.0 cm. The outer surface of the specimen is inked black. The cut surface does not reveal any masses or lesions. The entire specimen is submitted in cassettes "J1" through "J3." Dictated by

Specimen K is labeled "right level 1" and consists of a fragment of fibroadipose tissue, muscle and a salivary gland measuring in total 7.0 x 4.5 x 3.0 cm. The cut surface reveals a friable, white lesion adjacent to the salivary gland measuring 2.5 x 2.0 x 2.0 cm. Sections are submitted as follows. Dictated by

Specimen L is labeled "anterior mandible" and consists of a portion of the anterior mandible measuring 6.2 x 2.0 x 1.5 cm. There are seven burr holes on the anterior aspect of the specimen. Sections are submitted as follows after decalcification. Dictated by

Specimen M is labeled "right neck level V" and consists a fragment of fibroadipose tissue measuring 9.0 x 4.5 x 2.0 cm. The specimen is dissected for lymph nodes which are submitted entirely as follows: Dictated by

Specimen N is labeled "right neck level 2, 3 and 4" and consists of a fragment of muscle and fibroadipose tissue measuring in total 11.0 x 4.5 x 4.0 cm. Multiple possible lymph nodes are identified ranging in size from 0.2 x 0.2 x 0.2 cm to 2.0 x 1.0 x 0.5 cm. The entire lymph nodes are submitted as follows. Dictated by

CASSETTE SUMMARY:

A1FS:	Periosteum exudate
A2FS:	Left posterior margin
A3FS:	Right posterior margin
A4FS:	Left lateral posterior margin
A5FS:	Right lateral posterior margin
A6FS:	Left lateral margin
A7FS:	Right lateral margin
A8FS:	Anterior gingival margin
A9FS:	Tumor with deep soft tissue
A10:	Closest deep margin on right posterior aspect, perpendicular
A11-A13:	Representative sections of tumor in relation to mandible
A14:	Tumor with relation to deep edge at left posterior aspect
A15:	Right mandibular margin after decalcification
A16:	Left mandibular margin after decalcification
B1,B2:	Representative sections of salivary gland
B3:	One lymph node from fibroadipose tissue, bisected and submitted entirely
C1:	One lymph node, bisected
C2:	One lymph node, bisected
C3:	One lymph node, bisected
D1:	One lymph node, bisected
D2:	One lymph node, bisected

[page 5 of 5]
D3: Two possible lymph nodes
E1: Five possible lymph nodes, whole
E2: Four possible lymph nodes, whole
F1: Three possible lymph nodes
F2: Three possible lymph nodes
F3: One possible lymph node, bisected
G1: Six possible lymph nodes
G2: Five possible lymph nodes
G3, G4: Two lymph nodes, bisected,
H1: Four possible lymph nodes, one inked blue and bisected
H2: Two lymph nodes, each bisected, one inked blue
H3: Two possible lymph nodes, one inked blue and bisected
H4: One possible lymph node
H5, H6: Representative sections of largest positive lymph node
H7: Representative sections of second largest positive lymph node
K1: One lymph node, serially sectioned and submitted entirely
K2, 3: Representative cross sections of lesion with salivary gland
K4: Representative section of salivary gland away from lesion
L1: Right mandibular margin after decalcification
L2: Left mandibular margin after decalcification
M1: Six possible lymph nodes
M2: Six possible lymph nodes
M3: Seven possible lymph nodes
M4: Seven possible lymph nodes
N1: One possible lymph node, trisected
N2: Two possible lymph nodes, one inked black and bisected
N3: Four possible lymph nodes
N4: Six possible lymph nodes
N5: Five possible lymph nodes
N6: One possible lymph node, bisected

Intraoperative Consult Diagnosis

A1FS: MANDIBLE, INTEROSSEOUS SOFT TISSUE (FROZEN SECTION): INVASIVE CARCINOMA.
A2FS-A8FS: 360 MUCOSAL SHAVE MARGIN (FROZEN SECTION): NEGATIVE FOR CARCINOMA (A2FS
FOUR LEVELS
EXAMINED).
A9FS: PERPENDICULAR SECTION OF TUMOR AND DEEP CLOSEST SOFT TISSUE MARGIN
(FROZEN
SECTION): BLACK INK MARGIN FREE OF TUMOR, ESTIMATED CLEARANCE DIFFICULT TO
MEASURE.
Frozen section results were communicated to the surgical team and were repeated back by

Pathologist:

Source: NCI Genomic Data Commons file 659c0b03-0e2d-4ada-9e9b-cca265e765f2 (TCGA-QK-A8Z7.5C352230-8E0A-4B49-BCA1-108987042D88.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).